Somatic mutation profile of tumor specimen C3L-06707-05 (aliquot CPT0420180009) from CPTAC case C3L-06707, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.5 years (19,168 days).
Specimen C3L-06707-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a936e087-64c2-4b00-a7e9-9583f548fdc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06707-31 (Blood Derived Normal), aliquot CPT0420120005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57ae176c-8b4a-402a-bf55-348adaf64091

The open-access MAF lists 105 somatic variants for this specimen: 76 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 26, Nonsense Mutation 2, Frame Shift Ins 2, Intron 2, Splice Site 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 106/737 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782816495; called by muse, mutect2, varscan2
- BDNF | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339220115, COSV59234219; called by muse, varscan2
- BMP7 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs1017902590, COSV67781417; called by muse, mutect2, varscan2
- CC2D1B | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 43/466 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145750942; called by muse, mutect2
- CDH11 | c.1159A>C p.S387R | Missense Mutation (SNP) | VAF 83/478 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99218206; called by muse, mutect2, varscan2
- CDH9 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV50400503; called by muse, mutect2, varscan2
- CLEC1B | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754369087, COSV100046061, COSV53725976; called by muse, mutect2, varscan2
- CRYGD | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 62/455 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as CM112329, COSV52205691; called by muse, mutect2, varscan2
- DGKI | c.2504C>A p.S835Y | Missense Mutation (SNP) | VAF 207/417 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55943588; called by muse, mutect2, varscan2
- DKK1 | c.566G>C p.C189S | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397550019; called by muse, mutect2, varscan2
- DUSP21 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 25/315 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs766627568, COSV59133782; called by muse, mutect2
- FBXO17 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 62/284 reads (22%) | catalogued as rs549735835, COSV53070190, COSV53071564; called by muse, varscan2
- FKTN | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.474); catalogued as rs149033995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD6 | c.1039C>T p.R347W (on ENST00000344768 / NM_001267046.2; = p.R339W on NM_152330.4) | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs139449598; called by muse, mutect2, varscan2
- GGA1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs952446933; called by muse, mutect2, varscan2
- GJA5 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 208/565 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs782417838, COSV54783568; called by muse, mutect2, varscan2
- GPR146 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 105/827 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.488); catalogued as rs1288102574; called by muse, mutect2, varscan2
- HAPLN1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 36/561 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs769791026, COSV57145273; called by muse, mutect2
- IL31RA | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 85/531 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs541834884; called by muse, mutect2, varscan2
- LRFN4 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 92/497 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770776175; called by muse, mutect2, varscan2
- NAV3 | c.6169C>A p.P2057T (on ENST00000397909 / NM_001024383.2; = p.P2035T on NM_014903.6) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57064863; called by muse, mutect2, varscan2
- NDOR1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 179/627 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs536654925; called by muse, mutect2, varscan2
- NEU3 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 116/1126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs557819590; called by muse, mutect2, varscan2
- NRG3 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 142/680 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs749016725, COSV100932526; called by muse, mutect2, varscan2
- OR2AJ1 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100561459; called by muse, mutect2, varscan2
- OXR1 | c.482G>C p.S161T (on ENST00000442977 / NM_001198532.1; = p.S160T on NM_018002.3) | Missense Mutation (SNP) | VAF 71/644 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV56327047; called by muse, mutect2, varscan2
- PAPPA | c.1829A>T p.K610M | Missense Mutation (SNP) | VAF 80/547 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072698; called by muse, mutect2, varscan2
- PARD3B | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs1238050752; called by muse, mutect2, varscan2
- SHOX | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 120/409 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1340369865; called by muse, mutect2, varscan2
- SLCO6A1 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 139/487 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.145); catalogued as COSV65813124; called by muse, mutect2, varscan2
- SOD3 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 44/583 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1440152134; called by muse, mutect2
- SPTA1 | c.6192A>C p.E2064D | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63751706; called by muse, mutect2, varscan2
- SYT1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs1450554643; called by muse, mutect2, varscan2
- TP53 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 143/403 reads (35%) | catalogued as COSV52992944; called by mutect2, pindel, varscan2
- TRPM1 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 97/482 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99856336; called by muse, mutect2, varscan2
- TSSK1B | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 139/489 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs201871941; called by muse, mutect2, varscan2
- ZNF484 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs1413269098; called by muse, mutect2, varscan2
- ZNF732 | c.1639A>G p.K547E | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1029881076; called by muse, mutect2
- A2M | c.3106C>A p.Q1036K | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACTRT2 | c.849C>G p.S283R | Missense Mutation (SNP) | VAF 99/497 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AXIN2 | c.2305_2306insG p.F769Cfs*24 | Frame Shift Ins (INS) | VAF 79/556 reads (14%) | called by mutect2, pindel, varscan2
- CA10 | c.90A>C p.E30D | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTLN | c.4018A>C p.I1340L | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CNTNAP5 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- COL6A3 | c.8857A>G p.R2953G | Missense Mutation (SNP) | VAF 88/553 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CPXM2 | c.2159A>C p.K720T | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DNAH5 | c.8552T>C p.V2851A | Missense Mutation (SNP) | VAF 138/577 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EIF2S2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIZ1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 123/492 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- H1-2 | c.625_627del p.A209del | In Frame Del (DEL) | VAF 42/242 reads (17%) | called by pindel, varscan2
- HR | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 63/453 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 73/636 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRGPRX3 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 51/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MSANTD2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 51/468 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEA | c.7209T>A p.N2403K | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NPBWR1 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 131/915 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OGDHL | c.1587C>A p.D529E | Missense Mutation (SNP) | VAF 44/495 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- OR8U1 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 150/453 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ORC3 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PALD1 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 184/544 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.45); called by muse, mutect2
- PKHD1L1 | c.8163_8164insG p.F2722Vfs*12 | Frame Shift Ins (INS) | VAF 91/911 reads (10%) | called by mutect2, pindel, varscan2
- PLEKHG7 | c.530+5G>C | Splice Region (SNP) | VAF 41/268 reads (15%) | called by muse, mutect2, varscan2
- PXDN | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 150/534 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RHCG | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIT1 | c.526A>T p.T176S | Missense Mutation (SNP) | VAF 223/736 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC25A52 | c.268T>A p.L90M (on ENST00000672005; = p.L80M on NM_001034172.4) | Missense Mutation (SNP) | VAF 192/496 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC6A15 | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM70 | c.372C>G p.Y124* | Nonsense Mutation (SNP) | VAF 55/544 reads (10%) | called by muse, mutect2
- TNR | c.3665G>A p.G1222D | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAM1L1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPOAP1 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 138/475 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VAV2 | c.1447C>T p.H483Y (on ENST00000371850 / NM_001134398.2; = p.H473Y on NM_003371.4) | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WEE2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 223/936 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- YTHDC2 | c.1211-1G>T p.X404_splice | Splice Site (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- ZMYM5 | c.907C>T p.P303S (on ENST00000337963 / NM_001142684.2; = p.F207= on NM_001039649.2) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ZNF573 | c.1420G>C p.E474Q (on ENST00000536220 / NM_001172692.1; = p.E416Q on NM_152360.3) | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ABCA13 | c.13464G>A p.L4488= | Silent (SNP) | VAF 152/662 reads (23%) | called by muse, mutect2, varscan2
- AC011005.1 | c.90C>T p.S30= | Silent (SNP) | VAF 104/809 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.3642T>C p.A1214= | Silent (SNP) | VAF 84/380 reads (22%) | called by mutect2, varscan2
- ANKRD33B | c.1299G>A p.A433= | Silent (SNP) | VAF 161/728 reads (22%) | called by muse, mutect2, varscan2
- C20orf96 | c.729G>A p.E243= (on ENST00000360321 / NM_153269.3; = p.E242= on NM_080571.1) | Silent (SNP) | VAF 70/530 reads (13%) | called by muse, mutect2
- CXCR2 | c.747C>T p.A249= | Silent (SNP) | VAF 29/768 reads (4%) | called by muse, mutect2
- DLGAP2 | c.1203C>T p.P401= | Silent (SNP) | VAF 97/656 reads (15%) | catalogued as rs774698555, COSV70102043; called by muse, mutect2, varscan2
- ENPP7 | c.429G>A p.P143= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs202186933, COSV100093587; called by muse, mutect2
- EP400 | c.1884T>G p.P628= | Silent (SNP) | VAF 97/586 reads (17%) | called by muse, mutect2, varscan2
- HOXC13 | c.90C>T p.G30= | Silent (SNP) | VAF 221/696 reads (32%) | called by mutect2, varscan2
- IRF2 | c.261C>T p.S87= | Silent (SNP) | VAF 79/320 reads (25%) | called by muse, mutect2, varscan2
- KCNC3 | c.2022C>T p.H674= | Silent (SNP) | VAF 122/548 reads (22%) | called by muse, mutect2, varscan2
- LAMC3 | c.4050C>A p.P1350= | Silent (SNP) | VAF 22/566 reads (4%) | catalogued as COSV62654162; called by muse, mutect2
- OBSCN | c.20331C>T p.G6777= | Silent (SNP) | VAF 112/760 reads (15%) | catalogued as rs559240494; called by muse, mutect2, varscan2
- OR5H8 | c.894T>C p.H298= | Silent (SNP) | VAF 46/141 reads (33%) | called by muse, varscan2
- PCDHA5 | c.129C>T p.F43= | Silent (SNP) | VAF 94/618 reads (15%) | catalogued as COSV65352581; called by muse, mutect2, varscan2
- PDGFC | c.657T>A p.T219= | Silent (SNP) | VAF 52/256 reads (20%) | called by muse, mutect2, varscan2
- RETNLB | c.63G>A p.G21= | Silent (SNP) | VAF 124/436 reads (28%) | catalogued as rs776732330; called by muse, mutect2
- RGSL1 | c.2874G>A p.R958= | Silent (SNP) | VAF 159/381 reads (42%) | called by muse, mutect2, varscan2
- SNRPN | c.339A>G p.G113= | Silent (SNP) | VAF 92/475 reads (19%) | catalogued as COSV57595031; called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.1092C>T p.A364= | Silent (SNP) | VAF 65/544 reads (12%) | catalogued as rs928584264; called by muse, mutect2, varscan2
- TDRD15 | c.864G>A p.T288= | Silent (SNP) | VAF 110/417 reads (26%) | catalogued as rs566716223; called by muse, mutect2, varscan2
- TMEM266 | c.897C>T p.A299= | Silent (SNP) | VAF 107/496 reads (22%) | called by muse, mutect2, varscan2
- TMPRSS12 | c.270G>A p.P90= | Silent (SNP) | VAF 102/558 reads (18%) | catalogued as rs1210576235; called by muse, mutect2, varscan2
- TRIM14 | c.51C>G p.V17= | Silent (SNP) | VAF 88/708 reads (12%) | catalogued as rs745398502; called by muse, mutect2, varscan2
- TRMT10C | c.288G>A p.E96= | Silent (SNP) | VAF 23/540 reads (4%) | called by muse, mutect2
- FKBP10 | c.-1C>T | 5'UTR (SNP) | VAF 74/452 reads (16%) | called by muse, mutect2, varscan2
- NELL2 | c.56-184C>A | Intron (SNP) | VAF 101/531 reads (19%) | called by muse, mutect2, varscan2
- UNC13B | c.761+5624C>G | Intron (SNP) | VAF 105/429 reads (24%) | called by muse, mutect2, varscan2
